Somatic mutation profile of tumor specimen TCGA-HT-A5RB-01A (aliquot TCGA-HT-A5RB-01A-11D-A289-08) from TCGA case TCGA-HT-A5RB, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 24.1 years (8,820 days).
Specimen TCGA-HT-A5RB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14422f3d-a646-401a-a434-de161561929a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-A5RB-10A (Blood Derived Normal), aliquot TCGA-HT-A5RB-10A-01D-A289-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4825faf3-41c6-457a-b572-e1319d9ac905

The open-access MAF lists 21 somatic variants for this specimen: 14 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 14, Silent 7.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 25/86 reads (29%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.614A>C p.Y205S | Missense Mutation (SNP) | VAF 60/70 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs1057520007, COSV52665440, COSV52677268, COSV52688506; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACER2 | c.445A>G p.I149V | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV61820868; called by muse, mutect2, varscan2
- CSF2RA | c.769G>A p.V257I | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs750017867, COSV62624945; called by muse, mutect2, varscan2
- DSG2 | c.1994A>G p.E665G | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55199764; called by muse, mutect2, varscan2
- LIMK1 | c.691A>G p.I231V | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV60281981; called by muse, mutect2
- MAP3K10 | c.1786T>C p.S596P | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as rs889961470, COSV53422776; called by muse, mutect2, varscan2
- NAT10 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.495); catalogued as rs748227063, COSV57664058; called by muse, mutect2, varscan2
- OR11H6 | c.533T>C p.I178T | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.07); catalogued as COSV59644338; called by muse, mutect2, varscan2
- OR5M8 | c.473A>G p.E158G | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as rs142719978, COSV59116981; called by muse, mutect2, varscan2
- PDGFRL | c.91A>G p.K31E | Missense Mutation (SNP) | VAF 106/254 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1173852950, COSV52412780; called by muse, mutect2, varscan2
- RAI1 | c.2984G>A p.G995D | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99883592; called by muse, mutect2
- TMC3 | c.1097T>C p.V366A | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as COSV63923358; called by muse, mutect2, varscan2
- ZNF616 | c.1622G>C p.R541T | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.911); catalogued as COSV57511359, COSV57511649; called by muse, mutect2, varscan2
- FAM3B | c.261C>T p.Y87= | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as rs376038821, COSV63613232; called by muse, mutect2, varscan2
- KCNT1 | c.2898G>A p.K966= (on ENST00000488444; = p.K985= on NM_020822.3) | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as COSV53702691; called by mutect2, varscan2
- KIR2DL4 | c.135G>A p.T45= (on ENST00000396284; = p.T6= on NM_001080770.2) | Silent (SNP) | VAF 82/236 reads (35%) | catalogued as rs1362709367; called by muse, mutect2, varscan2
- LRIT1 | c.42G>A p.A14= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs202166415; called by muse, mutect2, varscan2
- MUC16 | c.3069A>G p.T1023= | Silent (SNP) | VAF 89/221 reads (40%) | catalogued as COSV67470491; called by muse, mutect2, varscan2
- SLX4 | c.3012C>T p.P1004= | Silent (SNP) | VAF 15/120 reads (13%) | catalogued as rs533668167, COSV53564321; ClinVar: likely benign; called by muse, mutect2, varscan2
- TNKS | c.2061C>T p.P687= | Silent (SNP) | VAF 34/89 reads (38%) | catalogued as rs372527063; called by muse, mutect2, varscan2
